Somatic mutation profile of tumor specimen TCGA-24-1471-01A (aliquot TCGA-24-1471-01A-01W-0551-08) from TCGA case TCGA-24-1471, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 60.5 years (22,081 days).
Specimen TCGA-24-1471-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7568d2fa-79c8-41bf-be10-39affc0a949d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-1471-10A (Blood Derived Normal), aliquot TCGA-24-1471-10A-01W-0551-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/51321c9e-77e6-447e-b2b7-04d3b80e7b08

The open-access MAF lists 38 somatic variants for this specimen: 29 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 6, Frame Shift Ins 3, Intron 2, Nonsense Mutation 2, Frame Shift Del 1, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EP300 | c.3934C>T p.R1312* | Nonsense Mutation (SNP) | VAF 153/341 reads (45%) | catalogued as rs1555911075, CM151330, COSV54328581; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.811G>T p.E271* | Nonsense Mutation (SNP) | VAF 120/131 reads (92%) | hotspot (GDC flag); catalogued as COSV52666332, COSV52700326, COSV52746468; called by muse, mutect2, varscan2
- ABCA1 | c.1394C>T p.A465V | Missense Mutation (SNP) | VAF 596/651 reads (92%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs551313050, COSV66066926; called by muse, mutect2, varscan2
- ADCY5 | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV71901519, COSV71901930; called by muse, mutect2, varscan2
- ADGRL3 | c.654G>T p.E218D (on ENST00000506720 / NM_001322402.2; = p.E150D on NM_015236.6) | Missense Mutation (SNP) | VAF 66/141 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101547180; called by muse, mutect2, varscan2
- ANO2 | c.2555A>G p.N852S (on ENST00000356134 / NM_001278597.3; = p.N856S on NM_001278596.3) | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs763260043, COSV59034776; called by muse, mutect2, varscan2
- CPS1 | c.1717G>T p.A573S | Missense Mutation (SNP) | VAF 59/196 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV51818349; called by muse, mutect2, varscan2
- DLGAP2 | c.393dup p.R132Afs*224 | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | catalogued as rs755665055; called by mutect2, pindel
- H1-4 | c.172T>C p.S58P | Missense Mutation (SNP) | VAF 21/24 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56802660; called by muse, mutect2, varscan2
- HRNR | c.748G>A p.G250S | Missense Mutation (SNP) | VAF 83/336 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.047); catalogued as rs1212756011, COSV64260793; called by muse, mutect2, varscan2
- ICAM1 | c.932C>T p.P311L | Missense Mutation (SNP) | VAF 82/167 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.112); catalogued as rs772315973, COSV53426303; called by muse, mutect2, varscan2
- ISX | c.166G>T p.G56C | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV58087742; called by muse, mutect2, varscan2
- LHX9 | c.95G>T p.G32V | Missense Mutation (SNP) | VAF 55/361 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (1); catalogued as COSV61330379; called by muse, mutect2, varscan2
- NKX2-3 | c.29C>T p.T10I | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60728609; called by muse, mutect2, varscan2
- OR51F1 | c.688A>G p.I230V | Missense Mutation (SNP) | VAF 160/436 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58580279; called by muse, mutect2, varscan2
- OR8H3 | c.489G>A p.M163I | Missense Mutation (SNP) | VAF 38/420 reads (9%) | SIFT tolerated (0.65); PolyPhen benign (0.029); catalogued as COSV57910312; called by muse, mutect2
- PCDHA4 | c.857C>T p.S286L | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.028); catalogued as rs781791401, COSV63538555; called by muse, mutect2, varscan2
- PEBP4 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 117/412 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56469721; called by muse, mutect2, varscan2
- PLSCR3 | c.287C>T p.T96M | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.766); catalogued as COSV61171577; called by muse, mutect2, varscan2
- PPP2R5A | c.970C>A p.Q324K | Missense Mutation (SNP) | VAF 82/503 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.152); catalogued as COSV54817854; called by muse, mutect2, varscan2
- SLC45A4 | c.1033dup p.R345Pfs*32 (on ENST00000517878 / NM_001286646.2; = p.R294Pfs*32 on NM_001080431.2) | Frame Shift Ins (INS) | VAF 4/25 reads (16%) | catalogued as rs768004505; called by pindel, varscan2
- SLC5A7 | c.1667C>G p.T556S | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as COSV99886731; called by muse, mutect2
- TBC1D4 | c.2359T>G p.S787A | Missense Mutation (SNP) | VAF 45/414 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.404); catalogued as COSV66490618; called by muse, mutect2, varscan2
- TRPM1 | c.2276C>T p.P759L | Missense Mutation (SNP) | VAF 13/14 reads (93%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.78); catalogued as rs566390005, COSV56638758; called by muse, mutect2, varscan2
- WDFY3 | c.8217+1G>T p.X2739_splice | Splice Site (SNP) | VAF 5/81 reads (6%) | catalogued as COSV99883727; called by muse, mutect2
- ZP4 | c.533C>T p.S178F | Missense Mutation (SNP) | VAF 154/665 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as COSV63912880; called by muse, mutect2, varscan2
- DPF3 | c.803dup p.S269Lfs*11 | Frame Shift Ins (INS) | VAF 10/74 reads (14%) | called by mutect2, varscan2
- LSMEM2 | c.443G>C p.S148T | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by mutect2, varscan2
- RBM45 | c.136_137del p.S46Afs*70 | Frame Shift Del (DEL) | VAF 15/87 reads (17%) | called by pindel, varscan2
- CPA1 | c.1171C>T p.L391= | Silent (SNP) | VAF 28/932 reads (3%) | catalogued as COSV99163271; called by muse, mutect2
- ESYT1 | c.2415G>A p.E805= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV57275131; called by muse, mutect2
- GPR22 | c.396C>T p.N132= | Silent (SNP) | VAF 61/224 reads (27%) | catalogued as COSV99772219; called by muse, mutect2, varscan2
- KIF22 | c.1791C>T p.N597= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as rs374212297; called by mutect2, varscan2
- OR5AK2 | c.399T>C p.T133= | Silent (SNP) | VAF 113/392 reads (29%) | catalogued as rs373245457; called by muse, mutect2, varscan2
- RAD18 | c.45C>T p.V15= | Silent (SNP) | VAF 22/103 reads (21%) | catalogued as rs1291027944, COSV53751301, COSV53751849; called by muse, mutect2, varscan2
- EPHA8 | c.1315+120T>G | Intron (SNP) | VAF 18/346 reads (5%) | catalogued as COSV99384934; called by muse, mutect2
- NOP10 | c.-1C>G | 5'UTR (SNP) | VAF 25/107 reads (23%) | catalogued as COSV100182336; called by muse, mutect2, varscan2
- OBSCN | c.11660-1995G>T | Intron (SNP) | VAF 31/887 reads (3%) | catalogued as COSV99478972; called by muse, mutect2
